Somatic mutation profile of tumor specimen 0DVSBW from CCDI case PBCNBA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Eye, NOS; Age at diagnosis: 5.5 years (2,020 days).
Specimen 0DVSBW: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94989490-cdda-4552-9694-d04f3305e4f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVSC8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f9ff20b-53a1-4b29-9311-ff707b959bba

The open-access MAF lists 36 somatic variants for this specimen: 24 protein-altering or splice-affecting, 6 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 6, 5'UTR 3, Nonsense Mutation 2, Intron 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CASK | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 121/134 reads (90%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as rs727503840, CM136390; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FGFR4 | c.1648G>C p.V550L | Missense Mutation (SNP) | VAF 194/441 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52800715, COSV52802492, COSV52804538; called by muse, mutect2, varscan2
- AARS2 | c.2368C>T p.R790* | Nonsense Mutation (SNP) | VAF 159/326 reads (49%) | catalogued as rs1480490090, COSV99771302; called by muse, mutect2, varscan2
- AMPH | c.1489G>A p.A497T | Missense Mutation (SNP) | VAF 17/506 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV100343939; called by muse, mutect2
- EFHB | c.2204G>A p.R735H | Missense Mutation (SNP) | VAF 140/504 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs150858538; called by muse, mutect2, varscan2
- HIVEP1 | c.4019A>G p.N1340S | Missense Mutation (SNP) | VAF 121/251 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0.042); catalogued as rs761031772; called by muse, mutect2, varscan2
- KIF14 | c.634C>G p.L212V | Missense Mutation (SNP) | VAF 123/285 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV66261821; called by muse, mutect2, varscan2
- LILRB5 | c.1733C>T p.P578L (on ENST00000449561 / NM_001081442.3; = p.P577L on NM_006840.5) | Missense Mutation (SNP) | VAF 166/616 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs749369808, COSV100300712; called by muse, mutect2, varscan2
- SLC22A10 | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.12); catalogued as rs369580475; called by muse, mutect2, varscan2
- SLC22A6 | c.629A>C p.N210T | Missense Mutation (SNP) | VAF 22/537 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100842866; called by muse, mutect2
- SPTBN1 | c.4942G>A p.V1648M | Missense Mutation (SNP) | VAF 146/473 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV61690039; called by muse, mutect2, varscan2
- SSR4 | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 121/136 reads (89%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as rs782739266; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VPS51 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 328/664 reads (49%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs1200261734; called by muse, mutect2, varscan2
- CACNG8 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 126/395 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- CDC14C | c.914G>C p.C305S (on ENST00000428251; = p.C198S on NM_152627.3) | Missense Mutation (SNP) | VAF 38/1128 reads (3%) | SIFT tolerated (0.94); PolyPhen benign (0.005); called by muse, mutect2
- DNAH5 | c.9742A>G p.K3248E | Missense Mutation (SNP) | VAF 91/225 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- DOCK9 | c.2095G>T p.A699S (on ENST00000376460 / NM_001366676.2; = p.A700S on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 187/560 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- EYS | c.1501T>A p.F501I | Missense Mutation (SNP) | VAF 135/281 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FAM170A | c.115A>T p.R39* | Nonsense Mutation (SNP) | VAF 125/282 reads (44%) | called by muse, mutect2, varscan2
- MAOA | c.1529C>T p.S510L | Missense Mutation (SNP) | VAF 168/180 reads (93%) | SIFT tolerated (0.34); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- NEFM | c.1054C>T p.H352Y | Missense Mutation (SNP) | VAF 88/662 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- NRG3 | c.187C>A p.Q63K | Missense Mutation (SNP) | VAF 124/136 reads (91%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- OR2V1 | c.523G>C p.V175L | Missense Mutation (SNP) | VAF 176/390 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- ROBO2 | c.664T>A p.F222I | Missense Mutation (SNP) | VAF 214/350 reads (61%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- CNTN2 | c.2805G>A p.V935= | Silent (SNP) | VAF 129/282 reads (46%) | called by muse, mutect2, varscan2
- DBN1 | c.1725G>A p.P575= | Silent (SNP) | VAF 103/280 reads (37%) | catalogued as rs138973815; called by muse, mutect2, varscan2
- GFI1B | c.955C>T p.L319= | Silent (SNP) | VAF 208/419 reads (50%) | catalogued as rs767791677; called by muse, mutect2, varscan2
- H4C9 | c.246C>A p.V82= | Silent (SNP) | VAF 196/481 reads (41%) | catalogued as COSV62890268; called by muse, mutect2, varscan2
- SCNN1G | c.1044G>A p.E348= | Silent (SNP) | VAF 106/285 reads (37%) | called by muse, mutect2, varscan2
- SPDYE3 | c.663C>G p.T221= | Silent (SNP) | VAF 54/140 reads (39%) | called by muse, mutect2, varscan2
- ANPEP | c.1437+30A>T | Intron (SNP) | VAF 241/1159 reads (21%) | called by muse, mutect2, varscan2
- CDH12 | c.-9C>G | 5'UTR (SNP) | VAF 50/104 reads (48%) | catalogued as COSV66401877; called by muse, mutect2, varscan2
- DEPP1 | c.*66G>C | 3'UTR (SNP) | VAF 200/316 reads (63%) | called by muse, mutect2, varscan2
- DHRS2 | c.732-83C>T | Intron (SNP) | VAF 12/71 reads (17%) | called by muse, mutect2, varscan2
- RAB22A | c.-89C>T | 5'UTR (SNP) | VAF 34/159 reads (21%) | catalogued as rs1450039505; called by muse, mutect2, varscan2
- ZKSCAN7 | c.-55C>G | 5'UTR (SNP) | VAF 16/74 reads (22%) | catalogued as COSV99837724; called by muse, mutect2, varscan2
